Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A22J, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A22J-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Path: Carcinoma, papillary and follicular 8340/3

CQCF: carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9 hr 4/22/11

Surgical Pathology Consultation Report

Patient Name:		Accession #:
MRN:		Collected:
DOB:		Received:
Gender: F	Service:	Reported:
HCN:	Visit #:	
Ordering MD:	Location:	
Copy To:	Facility:	

Specimen(s) Received

1. Thyroid: left thyroid; stitch/marks upper pole

Diagnosis

Papillary carcinoma, mixed solid and follicular variant with oncocytic change, 2.5 cm; mild nodular hyperplasia: Thyroid

No pathological diagnosis: Lymph node, isthmus
- Left hemithyroidectomy specimen

Synoptic Data

Procedure:	Left hemithyroidectomy
Received:	Fresh
Specimen Integrity:	Fragmented
Specimen Size:	Left lobe: 3.9 cm 3.0 cm 3.0 cm Isthmus +/- pyramidal lobe: 1.8 cm 0.7 cm 0.5 cm
Specimen Weight:	18.2 g
Tumor Focality:	Unifocal
----- DOMINANT TUMOR -----	
Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 2.5cm Additional dimension: 2.5 cm Additional dimension: 2.5 cm
Histologic Type:	Papillary carcinoma, follicular variant Papillary carcinoma, oncocytic or oxyphilic variant Papillary carcinoma, solid variant

Diagnostic Discrepancy	☒	☐
Reviewed/Initials	hr 4/22/11	

PW TSS on 2/20/13, TCGA tumor is
100% follicular variant.

[page 2 of 2]
	Follicular architecture
	Solid architecture
	Classical cytomorphology
	Oncocytic or oxyphilic cytomorphology
Histologic Grade:	Not applicable
Margins:	Cannot be assessed
Tumor Capsule:	Totally encapsulated
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 1 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Comment

The tumor is a mixed solid and follicular variant papillary carcinoma with oncocytic change. The tumor reaches at several points the painted surgical margins; however, the outer surface of the left lobe is not received intact. Therefore, the surgical margins cannot be assessed properly. There is single cell necrosis in some regions of the tumor, but these areas are associated with sites of degeneration. Therefore, there is no unequivocal evidence of dedifferentiation in this tumor.

Electronically

verified by:

Clinical History

Thyroid nodule

Gross Description

The specimen labeled with the patient's name and as "left thyroid stitch marks upper pole", consists of a one hemithyroidectomy specimen that weighs 18.2 g. The left lobe capsule is not received intact. The lobe measures 3.9 cm SI x 3.0 cm ML x 3.0 cm AP and the isthmus measures 1.8 SI x 0.5 cm ML x 0.7 cm AP. No parathyroid glands or lymph nodes are identified grossly. The left lobe contains one well delineated nodule that measure 2.5 cm SI x 2.5 cm ML x 2.5 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Two sections of nodule and one piece of normal tissue from the isthmus are stored frozen. The remainder of the specimen is submitted as follows:

1A-R Left lobe, superior to inferior
1E-F, H-I, K-L, N-O, P-Q: one piece bisected in each set of blocks
1S isthmus

Source: NCI Genomic Data Commons file 0d7b3069-2515-449d-a3f0-5cf0cb9b94e6 (TCGA-EM-A22J.D007B2FA-8E60-4C50-832B-7E3E320DDD97.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).